Somatic mutation profile of tumor specimen TCGA-EJ-A46D-01A (aliquot TCGA-EJ-A46D-01A-21D-A257-08) from TCGA case TCGA-EJ-A46D, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 53.3 years (19,466 days).
Specimen TCGA-EJ-A46D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e19e970-5715-49a6-b62b-695f73426824.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-A46D-10A (Blood Derived Normal), aliquot TCGA-EJ-A46D-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f7660ad-f671-4a1c-af9c-caf0ee9076d4

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANXA4 | c.632T>G p.F211C | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67849420; called by muse, mutect2
- COQ3 | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV54641407; called by muse, mutect2, varscan2
- SERPIND1 | c.1431C>G p.F477L | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV53140624; called by muse, mutect2, varscan2
- SLC6A20 | c.723G>T p.W241C | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62072488; called by muse, mutect2
- UGT1A8 | c.838G>T p.G280* | Nonsense Mutation (SNP) | VAF 14/332 reads (4%) | catalogued as COSV65073494, COSV65084721; called by muse, mutect2
- VLDLR | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.487); catalogued as COSV66074558; called by muse, mutect2, varscan2
- WDFY3 | c.446T>C p.V149A | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as COSV55712099; called by muse, mutect2, varscan2
- PRX | c.2874G>A p.K958= | Silent (SNP) | VAF 13/157 reads (8%) | catalogued as COSV52532835, COSV99397394; called by muse, mutect2
- RBM6 | c.543T>C p.Y181= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as rs1025795210, COSV56487208; called by muse, mutect2, varscan2
